Gene-level copy-number profile of tumor specimen TCGA-XC-AA0X-01A from TCGA case TCGA-XC-AA0X, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.2 years (28,211 days).
Specimen TCGA-XC-AA0X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2f00e27e-99a1-4334-85f3-730cc2c84c27.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XC-AA0X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4706bee8-ac38-404a-9fac-78ebc59b0470

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 10,037; copy number 2: 33,460; copy number 3: 13,176; copy number 4: 1,131; copy number 5: 572; copy number 7: 834; copy number 8: 12; copy number 9: 297; copy number 10: 13; copy number 11: 94; copy number 12: 187.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XC-AA0X-01A-32D-A400-01): tumor purity 0.21, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,009 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:154,272,546–198,222,513, 779 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–17,276,843, 302 genes, copy number 5 (broad region; genes not listed).
- chr6:53,497,341–54,625,488, 19 genes, copy number 5 (within-gene range 2–5): GCLC, AL033397.2, AL033397.1, LINC01564, KLHL31, AL590652.1, LRRC1, AL033384.2, MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44.
- chr8:37,405,439–43,514,421, 164 genes, copy number 5 (broad region; genes not listed).
- chr9:123,485,529–123,493,156, 2 genes, copy number 5: MIR7150, AL445489.1.
- chr12:40,140,926–48,570,066, 171 genes, copy number 7–11 (broad region; genes not listed).
- chr14:36,677,921–38,213,067, 20 genes, copy number 5–10 (within-gene range 2–10): SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517, AL359233.1, AL392023.2, AL392023.1, SSTR1.
- chr19:14,689,801–16,066,312, 77 genes, copy number 5 (broad region; genes not listed).
- chr19:16,074,293–16,077,395, 1 gene, copy number 5: AC008894.3.
- chr19:28,294,093–40,629,818, 474 genes, copy number 9–12 (within-gene range 2–12) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,037. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
